Somatic mutation profile of tumor specimen TCGA-CM-6170-01A (aliquot TCGA-CM-6170-01A-11D-1650-10) from TCGA case TCGA-CM-6170, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 73.0 years (26,663 days).
Specimen TCGA-CM-6170-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecbe5f80-6e47-4188-98c5-f1c4f3bb82dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6170-10A (Blood Derived Normal), aliquot TCGA-CM-6170-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bee5364-9d14-411f-89ab-70627231df79

The open-access MAF lists 101 somatic variants for this specimen: 74 protein-altering or splice-affecting, 27 silent.
By variant classification: Missense Mutation 62, Silent 27, Nonsense Mutation 5, Splice Region 3, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 76/241 reads (32%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.4886G>A p.R1629Q (on ENST00000333535 / NM_198056.3; = p.R1628Q on NM_000335.5) | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs199473623, CM100748, COSV61115745; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALX4 | c.1025G>C p.G342A | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV61326274; called by muse, varscan2
- AMIGO3 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV57538418; called by muse, mutect2, varscan2
- ANKRD26 | c.5071G>C p.D1691H | Missense Mutation (SNP) | VAF 157/356 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV101063470, COSV65776956; called by muse, mutect2, varscan2
- ASAP2 | c.849+2T>C p.X283_splice | Splice Site (SNP) | VAF 43/142 reads (30%) | catalogued as COSV55631129; called by muse, mutect2, varscan2
- ASXL1 | c.1719G>A p.R573= | Splice Region (SNP) | VAF 17/102 reads (17%) | catalogued as COSV60107450; called by muse, mutect2, varscan2
- BSPRY | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs759679791, COSV53057067; called by muse, mutect2, varscan2
- C21orf58 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as rs867778949, COSV52449546; called by muse, mutect2, varscan2
- CAMKV | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1220869354, COSV56555172; called by muse, mutect2, varscan2
- CASP9 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 102/282 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV61601407; called by muse, mutect2, varscan2
- CATSPERD | c.598G>T p.G200* | Nonsense Mutation (SNP) | VAF 326/807 reads (40%) | catalogued as rs770610933, COSV101062336, COSV67534579; called by muse, mutect2, varscan2
- CLASRP | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); catalogued as rs776111579, COSV99674210; called by muse, mutect2, varscan2
- CLCN2 | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1219041452, COSV55599300; called by muse, mutect2, varscan2
- CNTLN | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 48/303 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV52076801; called by muse, mutect2, varscan2
- COL12A1 | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as rs1013873051, COSV59393271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDN | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); catalogued as COSV60292540; called by muse, mutect2, varscan2
- DENND11 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as rs184004901, COSV72097653; called by muse, mutect2, varscan2
- DMBT1 | c.4876C>T p.R1626C (on ENST00000338354 / NM_001377530.1; = p.R869C on NM_004406.3) | Missense Mutation (SNP) | VAF 593/1296 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs374958699, COSV57565056; called by muse, mutect2, varscan2
- DMD | c.8911C>G p.L2971V | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58908057; called by muse, mutect2, varscan2
- DNAH1 | c.5786C>T p.S1929L | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs554663244, COSV70227201; called by muse, mutect2, varscan2
- DYNC1I1 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 102/155 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV61456086; called by muse, mutect2, varscan2
- EFHB | c.2168C>T p.P723L | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55547621; called by muse, mutect2, varscan2
- EIF4G2 | c.2432C>T p.S811F | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV101151181; called by muse, mutect2, varscan2
- FAM110B | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as rs763429337, COSV64064186; called by muse, mutect2, varscan2
- FAM78B | c.782A>C p.K261T | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV57976661, COSV57979347; called by muse, varscan2
- FAM78B | c.692dup p.N232* | Frame Shift Ins (INS) | VAF 40/122 reads (33%) | catalogued as rs763715884; called by pindel, varscan2
- FBXO40 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs200897227, COSV57523787; called by muse, mutect2, varscan2
- FEZ1 | c.755A>T p.Q252L | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV54028316; called by muse, mutect2, varscan2
- FLRT1 | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs777150139, COSV55359881; called by mutect2, varscan2
- FZD6 | c.1877C>G p.S626C | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV62471306; called by muse, mutect2, varscan2
- GATA2 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV62004179; called by muse, mutect2, varscan2
- GLOD5 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 54/154 reads (35%) | catalogued as rs782200472, COSV57489108; called by muse, mutect2, varscan2
- GPR155 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 10/128 reads (8%) | catalogued as rs1466752783, COSV55037072; called by muse, mutect2
- GPT2 | c.397A>C p.K133Q | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs752970046, COSV60838427; called by muse, mutect2, varscan2
- HELLS | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as COSV53296637; called by muse, mutect2, varscan2
- HNRNPH1 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV61485635; called by muse, mutect2, varscan2
- KCNQ5 | c.1236A>C p.E412D | Missense Mutation (SNP) | VAF 217/570 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as COSV59658762; called by muse, mutect2, varscan2
- KLHL36 | c.863C>T p.T288M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1462816698, COSV50718800; called by muse, mutect2, varscan2
- KRTAP4-3 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs751921358, COSV66940684; called by muse, mutect2, varscan2
- LCMT2 | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs375100125, COSV59790309, COSV59790918; called by muse, mutect2, varscan2
- LMAN1 | c.1442T>A p.F481Y | Missense Mutation (SNP) | VAF 91/170 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51826729; called by muse, mutect2, varscan2
- LRRC37A2 | c.4928C>T p.S1643L | Missense Mutation (SNP) | VAF 117/526 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV60236202; called by muse, mutect2, varscan2
- MAP3K15 | c.3294C>T p.A1098= | Splice Region (SNP) | VAF 27/90 reads (30%) | catalogued as rs140041575, COSV100135951; called by muse, mutect2, varscan2
- MBOAT7 | c.1115G>A p.C372Y | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1490768673, COSV55475621; called by muse, mutect2, varscan2
- MGAM | c.5156G>T p.W1719L | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV72074555; called by muse, mutect2, varscan2
- MORC4 | c.1846A>G p.S616G | Missense Mutation (SNP) | VAF 145/476 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55241714; called by muse, mutect2, varscan2
- NAV1 | c.3843C>T p.T1281= | Splice Region (SNP) | VAF 71/165 reads (43%) | catalogued as rs772481937, COSV55217227; called by muse, mutect2, varscan2
- NBEA | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 99/488 reads (20%) | catalogued as COSV59780988; called by muse, mutect2, varscan2
- PADI1 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 84/243 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64938310; called by muse, mutect2, varscan2
- PCDHA11 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 91/282 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.117); catalogued as COSV56497882; called by muse, mutect2, varscan2
- PCDHA4 | c.2063G>A p.G688D | Missense Mutation (SNP) | VAF 117/302 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as rs782209352, COSV100793816; called by muse, mutect2, varscan2
- PLPPR5 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs978208719, COSV54172493; called by muse, mutect2
- PPFIA2 | c.2971G>A p.A991T | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV61030701; called by muse, mutect2, varscan2
- RALGDS | c.1001A>G p.E334G | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100924571; called by muse, mutect2, varscan2
- RIPOR3 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201920244, COSV50388286; called by muse, mutect2, varscan2
- RRS1 | c.979_1011del p.P327_G337del | In Frame Del (DEL) | VAF 32/94 reads (34%) | catalogued as rs769712999; called by mutect2, varscan2
- SLC44A2 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 179/533 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs749777162, COSV59836017; called by muse, mutect2, varscan2
- SMAD4 | c.1094G>A p.G365D | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61684480; called by muse, mutect2
- SMARCA4 | c.3542A>C p.H1181P | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100759258, COSV60791110; called by muse, mutect2, varscan2
- SMYD4 | c.2326G>C p.G776R | Missense Mutation (SNP) | VAF 140/238 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54616161; called by muse, mutect2, varscan2
- SNED1 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs758442640, COSV60023569; called by muse, mutect2, varscan2
- SOHLH2 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 44/558 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100499560, COSV58522888; called by muse, mutect2
- SPAG17 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 169/410 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV60458058; called by muse, mutect2, varscan2
- TBXAS1 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 71/132 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV54944668; called by muse, mutect2, varscan2
- TBXT | c.308A>G p.K103R | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV51617644; called by muse, mutect2, varscan2
- TFEB | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs775220771, COSV57824723; called by muse, mutect2, varscan2
- THSD7B | c.2396G>A p.R799Q | Missense Mutation (SNP) | VAF 90/263 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV99759126; called by muse, mutect2, varscan2
- TMPRSS9 | c.1711C>T p.R571C (on ENST00000648592; = p.R537C on NM_182973.2) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs536594781, COSV60227338; called by muse, mutect2, varscan2
- TNXB | c.6910G>A p.G2304S (on ENST00000647633; = p.G2057S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756050937, COSV64478369; called by muse, mutect2, varscan2
- CHD7 | c.5509G>A p.D1837N | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2
- KCNH7 | c.2414del p.N805Mfs*21 | Frame Shift Del (DEL) | VAF 42/118 reads (36%) | called by mutect2, pindel, varscan2
- KIZ | c.1618T>G p.S540A | Missense Mutation (SNP) | VAF 122/186 reads (66%) | SIFT tolerated (0.15); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- WFIKKN2 | c.433A>C p.T145P | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ABCB8 | c.234C>A p.P78= (on ENST00000297504 / NM_001282291.2; = p.P61= on NM_007188.5) | Silent (SNP) | VAF 66/117 reads (56%) | catalogued as rs76801918, COSV52504287; called by muse, mutect2, varscan2
- ADRA1D | c.969C>T p.S323= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs770973888, COSV101063218, COSV65240716; called by muse, mutect2, varscan2
- BIRC6 | c.4818G>A p.S1606= | Silent (SNP) | VAF 105/333 reads (32%) | catalogued as rs761024593, COSV70198764; called by muse, mutect2, varscan2
- CARD14 | c.1812G>A p.A604= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs367702181; called by muse, mutect2, varscan2
- CCT3 | c.27G>A p.V9= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV55288775; called by muse, mutect2, varscan2
- CHD4 | c.1932G>A p.E644= (on ENST00000357008 / NM_001363606.2; = p.E657= on NM_001273.5) | Silent (SNP) | VAF 48/154 reads (31%) | catalogued as rs1419755575, COSV58900583; called by muse, mutect2, varscan2
- CLUH | c.3240C>T p.T1080= (on ENST00000435359; = p.T1119= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs1018767226, COSV70928605; called by muse, mutect2, varscan2
- COL27A1 | c.2961G>A p.P987= | Silent (SNP) | VAF 142/336 reads (42%) | catalogued as rs376303544; called by muse, mutect2, varscan2
- COL27A1 | c.4914C>T p.D1638= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs768707968, COSV61925639; called by muse, mutect2, varscan2
- DNAH5 | c.1821T>C p.Y607= | Silent (SNP) | VAF 103/270 reads (38%) | catalogued as rs1201876255, COSV54222085; called by muse, mutect2, varscan2
- EPHB6 | c.1746T>A p.P582= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV63891619; called by muse, mutect2, varscan2
- FCGBP | c.5589G>A p.T1863= | Silent (SNP) | VAF 54/207 reads (26%) | catalogued as rs1227400473; called by muse, mutect2, varscan2
- FURIN | c.1572C>T p.S524= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as rs752076063, COSV51576533; called by muse, mutect2, varscan2
- INSC | c.462C>T p.S154= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs1238626126, COSV65410328; called by muse, mutect2, varscan2
- IRS4 | c.3678G>A p.P1226= | Silent (SNP) | VAF 90/263 reads (34%) | catalogued as rs1223140636, COSV64532998; called by muse, mutect2, varscan2
- KNDC1 | c.3756C>T p.A1252= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs780524402, COSV58832737; called by muse, mutect2, varscan2
- MAPK4 | c.633C>T p.D211= | Silent (SNP) | VAF 41/74 reads (55%) | catalogued as rs978461250, COSV68542001; called by muse, mutect2, varscan2
- MFSD2B | c.612C>T p.S204= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as rs752900419, COSV57854642; called by muse, mutect2, varscan2
- MUC16 | c.16635A>G p.T5545= | Silent (SNP) | VAF 175/482 reads (36%) | catalogued as COSV67463105; called by muse, mutect2, varscan2
- POLQ | c.3084G>A p.L1028= | Silent (SNP) | VAF 85/228 reads (37%) | catalogued as COSV51750969; called by muse, mutect2, varscan2
- POLRMT | c.1500G>A p.L500= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV73933236; called by muse, mutect2, varscan2
- PTPRT | c.1782C>T p.Y594= | Silent (SNP) | VAF 43/225 reads (19%) | catalogued as rs377291418; ClinVar: likely benign; called by muse, mutect2, varscan2
- RBM12B | c.393G>A p.G131= | Silent (SNP) | VAF 22/344 reads (6%) | catalogued as COSV101197169; called by muse, mutect2
- RHOQ | c.384C>T p.D128= | Silent (SNP) | VAF 181/514 reads (35%) | catalogued as rs750487279, COSV53190022; called by muse, mutect2, varscan2
- STAB1 | c.5919C>A p.G1973= | Silent (SNP) | VAF 106/241 reads (44%) | catalogued as rs770760877, COSV100194493, COSV100195566; called by muse, mutect2, varscan2
- ZNF696 | c.612G>A p.T204= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV57524580; called by muse, mutect2, varscan2
- ZNF831 | c.624C>T p.G208= | Silent (SNP) | VAF 27/41 reads (66%) | catalogued as COSV64039746; called by muse, mutect2, varscan2
